Somatic mutation profile of tumor specimen 0DM69Y from CCDI case PBBXLF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.0 years (3,275 days).
Specimen 0DM69Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 071acd76-726c-4978-b7c9-6d27ebba9443.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM69I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5590f15b-c34c-4035-aec4-4854872a10e3

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 3, 3'UTR 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 547/1326 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as rs750971248, COSV57660957; called by muse, mutect2, varscan2
- MPZL3 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 432/1104 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1249904925; called by muse, mutect2, varscan2
- MUC16 | c.24148A>T p.T8050S | Missense Mutation (SNP) | VAF 432/1260 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs765084325; called by muse, mutect2, varscan2
- ADCY6 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 424/846 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CATSPER1 | c.2022C>A p.F674L | Missense Mutation (SNP) | VAF 40/1402 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- MYH3 | c.5434C>A p.Q1812K | Missense Mutation (SNP) | VAF 528/1648 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2
- OR4E1 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 255/675 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- PLA2G12A | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 114/1314 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMC5 | c.206dup p.S70Ifs*40 | Frame Shift Ins (INS) | VAF 529/1684 reads (31%) | called by mutect2, pindel, varscan2
- TBC1D25 | c.1381A>G p.R461G | Missense Mutation (SNP) | VAF 430/961 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 30/674 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- CLEC1A | c.165G>A p.L55= | Silent (SNP) | VAF 614/1686 reads (36%) | catalogued as rs1365218957; called by muse, mutect2, varscan2
- HPN | c.753C>T p.S251= | Silent (SNP) | VAF 104/1460 reads (7%) | catalogued as rs779672765, COSV52883151; called by muse, mutect2
- KDR | c.3694C>A p.R1232= | Silent (SNP) | VAF 381/1169 reads (33%) | called by muse, mutect2, varscan2
- KIAA1549 | c.1737G>A p.P579= | Silent (SNP) | VAF 208/3653 reads (6%) | catalogued as rs570277151, COSV54330692; ClinVar: likely benign; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 58/1485 reads (4%) | called by muse, mutect2
- DBNDD2 | c.*14C>A | 3'UTR (SNP) | VAF 262/668 reads (39%) | called by muse, mutect2, varscan2
- DUSP4 | c.-94C>T | 5'UTR (SNP) | VAF 42/127 reads (33%) | catalogued as rs561388005; called by muse, mutect2, varscan2
- EDA2R | c.*155G>T | 3'UTR (SNP) | VAF 180/432 reads (42%) | called by muse, mutect2, varscan2
- MGAT4D | c.877+17C>T | Intron (SNP) | VAF 64/603 reads (11%) | called by muse, mutect2, varscan2
- POR | c.189-4266C>G | Intron (SNP) | VAF 68/222 reads (31%) | called by muse, mutect2, varscan2
- UBXN6 | c.616-87C>T | Intron (SNP) | VAF 59/137 reads (43%) | catalogued as rs992199886; called by muse, mutect2, varscan2
